TCGA case TCGA-3G-AB19 — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/81fdc97f-8bad-4286-9d36-9a887c6b59a1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Dead; Days to death: 2,910 days (8.0 years).

Diagnoses (4)
1. Thymoma, type A, malignant (the primary disease): ICD-O-3 morphology code: 8581/3; ICD-10 code: C37; Tissue or organ of origin: Thymus; Site of resection or biopsy: Thymus; Classification of tumor: primary; Age at diagnosis: 76.2 years (27,827 days); Year of diagnosis: 2006; Method of diagnosis: Fine Needle Aspiration; Masaoka stage: Stage IIb; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 2,910 days (8.0 years).
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 147 days; Days to treatment end: 152 days; Treatment dose: 7 Gy; Treatment outcome: Complete Response; Number of fractions: 4; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS.
2. Synchronous primary of the kidney (histology not recorded by GDC). Age at diagnosis: 76.3 years (27,862 days); Days to diagnosis: 35 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 35 days; Treatment anatomic sites: Kidney.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Subsequent primary of the lung (histology not recorded by GDC). Age at diagnosis: 82.8 years (30,247 days); Days to diagnosis: 2,420 days (6.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.
4. Subsequent primary of the lung (histology not recorded by GDC). Age at diagnosis: 82.8 years (30,255 days); Days to diagnosis: 2,428 days (6.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 2,756 days (7.5 years); Disease response: Tumor Free.
- Days to follow up: 2,910 days (8.0 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Myasthenia Gravis; Risk factors: Myasthenia Gravis.
- Timepoint category: Initial Diagnosis; Weight: 112 kg; Height: 149 cm; BMI: 50.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3G-AB19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 210 mg.
  Slide TCGA-3G-AB19-01A-02-TS2: Section location: Top; Percent tumor cells: 92; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 8; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3G-AB19-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3G-AB19-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 230 mg.
  Slide TCGA-3G-AB19-11A-02-TS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 96; Percent necrosis: 0; Percent stromal cells: 4; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Stage record: Masaoka stage: IIb.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type A.
- Primary pathology: Method initial path diagnosis: Fine needle aspiration biopsy; History myasthenia gravis: Yes.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site: Lung; New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Kidney.
- Other malignancy form, Surgery: Other malignancy surgery type: nephrectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,910 days; disease-specific survival: no event (censored), 2,910 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,420 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3G-AB19-01A-21D-A422-01): tumor purity 0.76, ploidy 1.99, whole-genome doublings 0.
